Somatic mutation profile of tumor specimen TCGA-D7-A74B-01A (aliquot TCGA-D7-A74B-01A-12D-A33T-08) from TCGA case TCGA-D7-A74B, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 52.2 years (19,066 days).
Specimen TCGA-D7-A74B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecff4f80-ea5d-4a8a-8dee-d0abc562c252.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A74B-10A (Blood Derived Normal), aliquot TCGA-D7-A74B-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcfe32d1-1593-48f5-90ff-b299fef1af68

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, Splice Site 2, Frame Shift Del 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSH | c.1412C>A p.S471* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as COSV101139786; called by muse, mutect2
- B4GAT1 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.044); catalogued as COSV100240181; called by muse, mutect2
- CCT3 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as COSV99827198; called by muse, mutect2, varscan2
- CYP51A1 | c.595del p.N199Mfs*10 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as rs768885299, CM1312803; called by mutect2, pindel, varscan2
- DDR1 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs138565451, COSV61320172; called by muse, mutect2
- H3C11 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1053913919, COSV100137792, COSV58900141; called by muse, mutect2
- HEATR4 | c.2798T>C p.L933P | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV100407980; called by muse, mutect2
- LRRC7 | c.2107+1G>A p.X703_splice (on ENST00000651989 / NM_001370785.2; = p.X670_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 5/62 reads (8%) | catalogued as rs1344591005, COSV99225564; called by muse, mutect2
- PCDHB4 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 24/385 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV52023885; called by muse, mutect2
- PHACTR3 | c.194A>T p.N65I | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV100732381; called by muse, mutect2
- PLXNA3 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.731); catalogued as rs782247717; called by muse, mutect2
- ROCK1 | c.2915-1G>A p.X972_splice | Splice Site (SNP) | VAF 4/69 reads (6%) | catalogued as COSV101296296; called by muse, mutect2
- SOX30 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99398292; called by muse, mutect2
- SUGP1 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55920607; called by muse, mutect2, varscan2
- TMCC1 | c.1283C>T p.S428L (on ENST00000393238 / NM_001349268.2; = p.S104L on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100260857; called by muse, mutect2
- TP53 | c.287_293del p.S96Ffs*25 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel
- CCDC116 | c.897C>G p.R299= | Silent (SNP) | VAF 13/192 reads (7%) | catalogued as COSV99488878; called by muse, mutect2
- FLG2 | c.6834A>G p.Q2278= | Silent (SNP) | VAF 12/298 reads (4%) | catalogued as COSV66168605, COSV66171573; called by muse, mutect2
- GRIA1 | c.984T>C p.A328= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99598947; called by muse, mutect2
- PHACTR3 | c.192G>A p.R64= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as COSV100732379; called by muse, mutect2
- RHBDF1 | c.1599C>T p.S533= | Silent (SNP) | VAF 10/137 reads (7%) | catalogued as rs1232198441, COSV99244420; called by muse, mutect2
- SENP5 | c.903T>C p.C301= | Silent (SNP) | VAF 7/147 reads (5%) | catalogued as COSV100051910; called by muse, mutect2
- SRRM2 | c.4503A>G p.S1501= | Silent (SNP) | VAF 11/202 reads (5%) | catalogued as COSV100070506; called by muse, mutect2
- TEX47 | c.598T>C p.L200= | Silent (SNP) | VAF 6/117 reads (5%) | catalogued as COSV99787223; called by muse, mutect2
- OR52A1 | c.*2A>C | 3'UTR (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100200452; called by muse, mutect2
